TARGET case TARGET-20-PAYKXV-Unsorted — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8c55ecb3-c780-40f8-a717-1b1b13c67db9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.8 years (276 days); Year of diagnosis: 2017; Days to last follow up: 5 days; Sites of involvement: Central nervous system.
   Treatment given: Protocol identifier: AAML1031.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.

Follow-up (1 entry)
- Days to follow up: 5 days; Event-free: no event (relapse, second malignancy or death) recorded through day 5; Year of follow up: 2017.

Molecular and laboratory tests (laboratory values grouped by visit day)
- CEBPA mutation, nos: Negative.
- FLT3 internal tandem duplication: Negative.
- KMT2A translocation: Positive.
- Monosomy 5: Negative.
- Monosomy 7: Negative.
- NPM1 mutation, nos: Negative.
- Test: Negative.
- Test: Negative; Chromosomal translocation: t(10;11)(p11.2;q23).
- Test: Negative; Chromosomal translocation: t(11;19)(q23;p13.1).
- Test: Negative; Chromosomal translocation: t(3;5)(q25;q34).
- Test: Negative; Chromosomal translocation: t(6;11)(q27;q23).
- Test: Negative; Chromosomal translocation: t(6;9).
- Test: Negative; Chromosomal translocation: t(8;21).
- Test: Negative; Chromosomal translocation: t(9;11)(p22;q23).
- Test: Negative; Chromosome arm: q.
- Trisomy 21: Negative.
- Trisomy 8: Negative.
- Day 0: Leukocytes 60.5 ×10³/µL; Blast Count 37.3%; Bone Marrow blast count 90%.

Biospecimens (1 sample)
- Sample TARGET-20-PAYKXV-Unsorted-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- First Event: Censored
- Event Free Survival Time in Days: 5
- Overall Survival Time in Days: 5
- WBC at Diagnosis: 60.5
- Bone marrow leukemic blast percentage (%): 90
- Peripheral blasts (%): 37.3
- CNS disease: Yes
- t(6;9): No
- t(8;21): No
- t(3;5)(q25;q34): No
- t(6;11)(q27;q23): No
- t(9;11)(p22;q23): No
- t(10;11)(p11.2;q23): No
- t(11:19)(q23:p13.1): No
- inv(16): No
- del5q: No
- del7q: No
- del9q: No
- monosomy 5: No
- monosomy 7: No
- trisomy 8: No
- trisomy 21: No
- MLL: Yes
- Minus Y: No
- Minus X: No
- Cytogenetic Code Other: der(1)t(1;6)(q32;q25)inv(1)(p34q32),der(6)t(1;6)(q32;q25),-20
- Cytogenetic Complexity: 4
- Primary Cytogenetic Code: MLL
- ISCN: 45,XY,der(1)t(1;6)(q32;q25)inv(1)(p34q32),der(6)t(1;6)(q32;q25),der(10) cryp ins(10;11)(p12;q23.3q23.3)del(10)(p15),der(11)(11pter->11q23::?::11q23->11qter),-20[19]
- FLT3/ITD positive?: No
- NPM mutation: No
- CEBPA mutation: No
- CR status at end of course 1: unevaluable
- CR status at end of course 2: unevaluable
- Risk group: Standard Risk
